Somatic mutation profile of tumor specimen TCGA-O2-A52S-01A (aliquot TCGA-O2-A52S-01A-11D-A25L-08) from TCGA case TCGA-O2-A52S, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage III; Age at diagnosis: 58.0 years (21,182 days).
Specimen TCGA-O2-A52S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2b3497b-03a2-473f-8002-539b0cbfdba7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-O2-A52S-10A (Blood Derived Normal), aliquot TCGA-O2-A52S-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76bcde92-fdb7-4ef7-a10c-e07b5d3060eb

The open-access MAF lists 405 somatic variants for this specimen: 316 protein-altering or splice-affecting, 76 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 76, Nonsense Mutation 31, Frame Shift Del 9, Intron 7, Splice Site 7, RNA 4, Splice Region 3, Frame Shift Ins 2, Translation Start Site 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>T p.X51_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | hotspot (GDC flag); catalogued as rs730881677, CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; ClinVar: pathogenic; called by muse, mutect2
- DICER1 | c.1356C>G p.Y452* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as rs1131691219, COSV100602352; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2A | c.1553G>T p.R518L | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs397518470, CM138249, COSV58023511, COSV58059710; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.725A>T p.K242I | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV99713682; called by muse, mutect2, varscan2
- ABCD2 | c.316T>C p.W106R | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV100429671; called by muse, mutect2, varscan2
- ACSS1 | c.1058A>G p.N353S | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100053901; called by muse, mutect2, varscan2
- ADCY4 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs147879547; called by muse, mutect2, varscan2
- ADGRB3 | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99486233; called by muse, mutect2, varscan2
- ADPRH | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777573670, COSV100813351; called by muse, mutect2, varscan2
- AGGF1 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs753113687, COSV100462100; called by muse, mutect2, varscan2
- AKAP3 | c.1952C>T p.S651F | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV99962413, COSV99962459; called by muse, mutect2, varscan2
- ALMS1 | c.3064G>T p.A1022S | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1267229357, COSV100043184; called by muse, mutect2, varscan2
- ALPK3 | c.4012C>A p.P1338T | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV99361045; called by muse, mutect2, varscan2
- ANKRD20A1 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs796959999; called by mutect2, varscan2
- ANKRD20A4P | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1365313153; called by mutect2, varscan2
- ARHGAP31 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99957427; called by muse, mutect2, varscan2
- ARHGAP31 | c.3971C>G p.S1324* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as COSV99957429; called by muse, mutect2, varscan2
- ARNT2 | c.1605G>T p.K535N | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.209); catalogued as COSV100309285; called by muse, mutect2, varscan2
- ATF7IP | c.2330C>G p.S777C | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99661951; called by muse, mutect2, varscan2
- ATMIN | c.663-1G>A p.X221_splice | Splice Site (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100214712; called by muse, mutect2
- ATP1A3 | c.2884T>C p.F962L (on ENST00000545399 / NM_001256214.2; = p.F949L on NM_152296.5) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100132435; called by muse, mutect2, varscan2
- BHLHE22 | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs529311968, COSV100417856; called by muse, mutect2, varscan2
- BICDL1 | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.23); catalogued as COSV99984656; called by muse, mutect2
- C1orf162 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100636230, COSV59058913; called by muse, mutect2, varscan2
- C5orf49 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.662); catalogued as rs200521160, COSV57899572; called by muse, mutect2, varscan2
- CA8 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV100527159; called by muse, mutect2, varscan2
- CACNA1E | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373651535, COSV62386777; called by muse, mutect2, varscan2
- CACNA1F | c.2870T>A p.I957N | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100545150; called by muse, mutect2, varscan2
- CANX | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs1450333440, COSV99910582; called by muse, mutect2, varscan2
- CARD17 | c.306A>T p.Q102H | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100995256; called by muse, mutect2, varscan2
- CARF | c.712A>T p.K238* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100247767; called by muse, mutect2, varscan2
- CARM1 | c.453G>A p.Q151= | Splice Region (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100499045; called by muse, mutect2, varscan2
- CCDC171 | c.3661G>C p.E1221Q | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV101048483, COSV66244680; called by muse, mutect2, varscan2
- CCNA2 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV99145013; called by muse, mutect2, varscan2
- CD163 | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.696); catalogued as COSV100776008, COSV100776076; called by muse, mutect2, varscan2
- CD1A | c.208T>G p.W70G | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99192535; called by muse, mutect2, varscan2
- CD1B | c.954C>A p.C318* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100939266; called by muse, mutect2, varscan2
- CD207 | c.660G>T p.E220D | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV101338579; called by muse, mutect2, varscan2
- CDH16 | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100234030; called by muse, mutect2, varscan2
- CDH4 | c.1050+1G>T p.X350_splice | Splice Site (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100849333; called by muse, mutect2
- CDHR4 | c.215G>T p.R72M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV100323699; called by muse, mutect2, varscan2
- CDK15 | c.389C>A p.A130D (on ENST00000652192 / NM_001366386.2; = p.A79D on NM_139158.2) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99643479; called by muse, mutect2, varscan2
- CENPN | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as rs745658924, COSV55141960; called by muse, mutect2, varscan2
- CFHR2 | c.590G>A p.W197* | Nonsense Mutation (SNP) | VAF 40/164 reads (24%) | catalogued as COSV100804370; called by muse, mutect2, varscan2
- CHST12 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759386693, COSV51678032; called by muse, mutect2, varscan2
- CHUK | c.934-2A>T p.X312_splice | Splice Site (SNP) | VAF 19/35 reads (54%) | catalogued as CS151931, COSV100957204; called by muse, varscan2
- CIB3 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.186); catalogued as COSV99521838; called by muse, mutect2, varscan2
- CILP2 | c.1639G>T p.V547L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1266686222, COSV52274272, COSV99364980; called by muse, mutect2, varscan2
- CILP2 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1473305567, COSV52280338; called by muse, mutect2
- CLEC4M | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as COSV99940721; called by muse, mutect2, varscan2
- CNGB3 | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as COSV100182587; called by muse, mutect2, varscan2
- CNTN3 | c.2138G>A p.S713N | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV55164936, COSV99725457; called by muse, mutect2, varscan2
- CNTN4 | c.2170C>A p.P724T | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100639488; called by muse, mutect2, varscan2
- CNTRL | c.2929A>C p.K977Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV99443155; called by muse, mutect2, varscan2
- COL1A2 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99800464; called by muse, mutect2, varscan2
- COL22A1 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.175); catalogued as COSV100277574; called by muse, mutect2, varscan2
- COL6A3 | c.3877G>A p.D1293N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as COSV99800005; called by muse, mutect2, varscan2
- COL6A5 | c.7443C>G p.I2481M (on ENST00000312481; = p.I2477M on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV55213083, COSV99593972; called by muse, mutect2, varscan2
- COMMD7 | c.542A>T p.Q181L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV99640756; called by muse, mutect2, varscan2
- CORO2A | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100674056; called by muse, varscan2
- CPNE3 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV99547885; called by muse, mutect2, varscan2
- CPNE3 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV52210591, COSV99547886; called by muse, mutect2, varscan2
- CPQ | c.779C>A p.A260E | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV99613651; called by muse, mutect2, varscan2
- CPQ | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.243); catalogued as COSV99613654; called by muse, mutect2, varscan2
- CRNN | c.469C>G p.Q157E | Missense Mutation (SNP) | VAF 123/490 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV99664249; called by muse, mutect2, varscan2
- CSMD1 | c.8135G>T p.R2712L (on ENST00000520002; = p.R2711L on NM_033225.6) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV100151381; called by muse, mutect2, varscan2
- CSMD1 | c.7235G>A p.R2412H (on ENST00000520002; = p.R2411H on NM_033225.6) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs201439492; called by muse, mutect2, varscan2
- CSMD3 | c.5498G>T p.G1833V (on ENST00000297405 / NM_001363185.1; = p.G1729V on NM_052900.3) | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52292825, COSV99841525; called by muse, varscan2
- CSMD3 | c.5438A>T p.D1813V (on ENST00000297405 / NM_001363185.1; = p.D1709V on NM_052900.3) | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99841527; called by muse, varscan2
- CSMD3 | c.4624G>A p.D1542N (on ENST00000297405 / NM_001363185.1; = p.D1438N on NM_052900.3) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV52349455; called by muse, mutect2, varscan2
- CUL3 | c.2226G>C p.K742N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758729540, COSV100024533; called by muse, mutect2, varscan2
- CUL3 | c.1378-1G>A p.X460_splice | Splice Site (SNP) | VAF 74/210 reads (35%) | catalogued as COSV52362106, COSV52363563; called by muse, mutect2, varscan2
- CYTIP | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99938829; called by muse, mutect2, varscan2
- DARS1 | c.544A>C p.N182H | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV99927749; called by muse, mutect2, varscan2
- DCAF4L2 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100150671, COSV60476277, COSV60478817; called by muse, mutect2, varscan2
- DGKI | c.2962G>A p.D988N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.468); catalogued as COSV55937324, COSV55942116, COSV99936094; called by muse, mutect2, varscan2
- DHRS2 | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99159703; called by muse, mutect2, varscan2
- DNMBP | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as COSV100144164; called by muse, mutect2, varscan2
- DOCK5 | c.2850C>T p.I950= | Splice Region (SNP) | VAF 9/17 reads (53%) | catalogued as rs780277079, COSV52395284, COSV99377355; called by muse, mutect2, varscan2
- DTX3 | c.853G>C p.A285P | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99678149; called by muse, mutect2, varscan2
- EBF2 | c.649A>T p.T217S | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV101282251; called by muse, mutect2, varscan2
- EEA1 | c.960G>C p.K320N | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100468211; called by muse, mutect2, varscan2
- EIF4E2 | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.2); catalogued as COSV99299233; called by muse, mutect2, varscan2
- EIF4G1 | c.3881G>A p.R1294H (on ENST00000346169 / NM_198241.3; = p.R1099H on NM_004953.5) | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1428683814, COSV100072110; called by muse, mutect2, varscan2
- ENPP1 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100719477; called by muse, mutect2, varscan2
- EPHA10 | c.2779C>A p.R927S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100361569; called by muse, mutect2, varscan2
- ERGIC2 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV100792018; called by muse, mutect2, varscan2
- FAM107B | c.307G>C p.E103Q (on ENST00000378458 / NM_001320737.1; = p.E278Q on NM_031453.3) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99474233; called by muse, mutect2, varscan2
- FAM135B | c.3714C>A p.N1238K | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV52735523; called by muse, mutect2, varscan2
- FAT4 | c.3475C>G p.H1159D | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.176); catalogued as COSV101272534; called by muse, mutect2, varscan2
- FBLN7 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs757716376, COSV55617337; called by muse, mutect2, varscan2
- FCSK | c.2882A>G p.H961R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1444974923, COSV99851125; called by muse, mutect2, varscan2
- FEZ1 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.185); catalogued as COSV99630928; called by muse, mutect2, varscan2
- FEZ1 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV99630929; called by muse, mutect2, varscan2
- FLG | c.10279T>C p.S3427P | Missense Mutation (SNP) | VAF 164/655 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100911870; called by muse, mutect2, varscan2
- FRY | c.734A>T p.K245M | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100969642; called by muse, mutect2, varscan2
- FSTL1 | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99820855; called by muse, mutect2, varscan2
- GABRB3 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as COSV100158669, COSV54676970; called by muse, mutect2, varscan2
- GCA | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs374402814, COSV99280629; called by muse, mutect2, varscan2
- GFRAL | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100475487, COSV100475585; called by muse, mutect2, varscan2
- GH2 | c.75T>G p.S25R | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100237056; called by muse, mutect2, varscan2
- GJA8 | c.782A>G p.Q261R | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV99569568; called by muse, mutect2, varscan2
- GPATCH8 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100132757; called by muse, mutect2, varscan2
- GRID2 | c.1588C>A p.R530S | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56185857, COSV99944022; called by muse, mutect2, varscan2
- GRIK5 | c.1888A>T p.I630F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99490182, COSV99491055; called by muse, mutect2, varscan2
- GRIN3B | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99312734; called by muse, varscan2
- GRM1 | c.2251C>A p.L751M | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as COSV51108138, COSV99267784; called by muse, mutect2, varscan2
- GRM3 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.919); catalogued as COSV64468590; called by muse, mutect2, varscan2
- GRM5 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 49/109 reads (45%) | catalogued as COSV100553329, COSV100554471; called by muse, mutect2, varscan2
- H3C1 | c.339C>G p.I113M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV55120451, COSV99772147; called by muse, mutect2, varscan2
- HECW2 | c.2680G>C p.A894P | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99648107; called by muse, mutect2, varscan2
- HGSNAT | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52816317, COSV99925395; called by muse, mutect2, varscan2
- HLX | c.713G>T p.S238I | Missense Mutation (SNP) | VAF 82/105 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV100854587; called by muse, mutect2, varscan2
- HOXD4 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100106951; called by muse, mutect2, varscan2
- IGF2BP1 | c.566C>G p.A189G | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99288865; called by muse, mutect2, varscan2
- IGKV1D-33 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as COSV101134078; called by muse, mutect2, varscan2
- INSIG2 | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99830599; called by muse, mutect2, varscan2
- INTS4 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV101417232; called by muse, mutect2, varscan2
- INTS4 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 42/206 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV101417233; called by muse, mutect2
- IQCN | c.2974C>A p.Q992K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100828371; called by muse, mutect2, varscan2
- ITCH | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99392892; called by muse, mutect2, varscan2
- ITCH | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs202036043, COSV99392895; called by muse, mutect2, varscan2
- ITSN2 | c.4919A>T p.D1640V | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100743924; called by muse, mutect2, varscan2
- JCAD | c.3985G>C p.E1329Q | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as COSV100948507, COSV64758139; called by muse, mutect2, varscan2
- KBTBD4 | c.906C>G p.N302K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV100442924; called by muse, mutect2, varscan2
- KCNK18 | c.196T>C p.C66R | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100572105; called by muse, mutect2, varscan2
- KCNV1 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as COSV99819284; called by muse, mutect2, varscan2
- KLHL20 | c.850A>T p.R284* | Nonsense Mutation (SNP) | VAF 29/55 reads (53%) | catalogued as COSV99268564; called by muse, mutect2, varscan2
- KLHL40 | c.1792C>G p.R598G | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV99825671, COSV99825706; called by muse, mutect2, varscan2
- KMT2D | c.4846G>T p.G1616* | Nonsense Mutation (SNP) | VAF 29/91 reads (32%) | catalogued as COSV56496382; called by muse, mutect2, varscan2
- KMT2D | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV56420720, COSV99984261; called by muse, mutect2, varscan2
- KMT5B | c.1978G>A p.G660S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100430359; called by muse, mutect2, varscan2
- KRT78 | c.1432A>T p.I478F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.11); catalogued as COSV100398500; called by muse, mutect2, varscan2
- KRTAP5-5 | c.692T>A p.V231E | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); catalogued as COSV101294193; called by muse, mutect2, varscan2
- LAMA3 | c.1610G>T p.W537L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100557249; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs557612026, COSV99523916; called by muse, mutect2, varscan2
- LPCAT4 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV100149130, COSV59218342; called by muse, mutect2, varscan2
- LPP | c.235A>T p.S79C | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV100447883; called by muse, mutect2, varscan2
- LRRC52 | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV54233200, COSV99674005; called by muse, mutect2, varscan2
- LRRTM1 | c.944T>A p.L315Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.401); catalogued as COSV99702890; called by muse, mutect2, varscan2
- LYST | c.10216A>G p.T3406A | Missense Mutation (SNP) | VAF 175/239 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV101089976; called by muse, mutect2, varscan2
- MADCAM1 | c.1006T>A p.L336M | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99298649; called by muse, mutect2, varscan2
- MAGEC1 | c.2705C>A p.P902H | Missense Mutation (SNP) | VAF 101/188 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99596113; called by muse, mutect2, varscan2
- MAPKAP1 | c.84G>C p.E28D | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99785404; called by muse, mutect2, varscan2
- MARCO | c.1211C>A p.S404Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.518); catalogued as COSV100503671; called by muse, mutect2, varscan2
- MAZ | c.1070G>C p.R357T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99361332; called by muse, mutect2, varscan2
- MFNG | c.497A>T p.Y166F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100812919, COSV63690052; called by muse, mutect2, varscan2
- MGRN1 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs766556602, COSV99273706, COSV99274472; called by muse, mutect2, varscan2
- MIEF1 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as COSV100307775; called by muse, mutect2, varscan2
- MITF | c.1044A>T p.K348N (on ENST00000448226 / NM_006722.3; = p.K248N on NM_000248.4) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100097208; called by muse, mutect2, varscan2
- MNT | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs748869504, COSV99438186; called by muse, mutect2, varscan2
- MRGPRX3 | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs369169253, COSV66933505; called by muse, mutect2, varscan2
- MS4A7 | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV100279686, COSV55729231; called by muse, mutect2, varscan2
- MSR1 | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100027685, COSV100028287; called by muse, mutect2, varscan2
- MTMR4 | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100051260; called by muse, mutect2, varscan2
- MUC5AC | c.15065C>T p.S5022L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs752465552, COSV100611538; called by mutect2, varscan2
- MUC5B | c.660T>A p.Y220* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101500579; called by muse, mutect2
- MUC5B | c.14901C>A p.C4967* | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as COSV101500580; called by muse, mutect2, varscan2
- MUC5B | c.14902C>G p.H4968D | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV101500581; called by muse, mutect2, varscan2
- MYO9A | c.6474G>C p.M2158I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV61852478, COSV61853409; called by muse, mutect2, varscan2
- NCOA6 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 83/132 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1330771895, COSV100750465, COSV62862902; called by muse, mutect2, varscan2
- NCOR1 | c.601A>T p.K201* | Nonsense Mutation (SNP) | VAF 22/44 reads (50%) | catalogued as COSV99251149; called by muse, mutect2, varscan2
- NDST4 | c.449T>C p.L150S | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99997262; called by muse, mutect2, varscan2
- NDUFV1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs767193537, COSV59595743; called by muse, mutect2, varscan2
- NEB | c.1595G>T p.S532I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as COSV99425760; called by muse, mutect2, varscan2
- NOS2 | c.3405G>T p.E1135D | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV100569796; called by muse, mutect2, varscan2
- NOVA1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99948226; called by muse, mutect2, varscan2
- NPAP1 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100274996; called by muse, mutect2, varscan2
- NRXN3 | c.947C>G p.S316* (on ENST00000557594 / NM_001272020.2; = p.S948* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 10/131 reads (8%) | catalogued as COSV55315400; called by muse, mutect2
- NTRK3 | c.1688C>A p.T563N | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV62308222; called by muse, mutect2, varscan2
- NUDT12 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100048274; called by muse, mutect2, varscan2
- OPRL1 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.151); catalogued as rs753546410, COSV100402192; called by muse, mutect2, varscan2
- OR10G4 | c.25G>C p.A9P | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100304693, COSV100304910; called by muse, mutect2, varscan2
- OR2A12 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101283184, COSV68821599, COSV99065260; called by muse, mutect2, varscan2
- OR2T5 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV63540843; called by muse, mutect2, varscan2
- OR4D5 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100189987; called by muse, mutect2, varscan2
- OR4D6 | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs749200311, COSV55659731; called by muse, mutect2, varscan2
- OR4S2 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100412735; called by muse, mutect2, varscan2
- OR6B1 | c.206T>A p.L69* | Nonsense Mutation (SNP) | VAF 43/132 reads (33%) | catalogued as COSV101281665; called by muse, mutect2, varscan2
- OR6N1 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100625255; called by muse, mutect2, varscan2
- ORC2 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 30/87 reads (34%) | catalogued as COSV99309654; called by muse, mutect2, varscan2
- OSCAR | c.118G>T p.G40* | Nonsense Mutation (SNP) | VAF 31/112 reads (28%) | catalogued as COSV99500022; called by muse, mutect2, varscan2
- OXLD1 | c.309C>G p.Y103* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as rs368222035, COSV100235755; called by muse, mutect2, varscan2
- PCDH15 | c.1235C>A p.A412E | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs970867980, COSV100224636; called by muse, mutect2, varscan2
- PCDH17 | c.2933T>C p.V978A | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100931793; called by muse, mutect2, varscan2
- PCDHGA12 | c.1879C>G p.R627G | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV99341392; called by muse, mutect2, varscan2
- PCDHGA2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1464332946, COSV53899369; called by muse, mutect2, varscan2
- PCIF1 | c.1819C>T p.H607Y | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV100533231; called by muse, mutect2, varscan2
- PCLO | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 112/315 reads (36%) | catalogued as COSV100435027; called by muse, mutect2, varscan2
- PDE1C | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100371980; called by muse, mutect2, varscan2
- PDE3A | c.3203G>T p.R1068M | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100762579, COSV62973144; called by muse, mutect2, varscan2
- PDE5A | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs752046787, COSV99308976; called by muse, mutect2, varscan2
- PDZD8 | c.2432A>G p.K811R | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as rs144686674; called by muse, mutect2, varscan2
- PEG3 | c.3166G>T p.E1056* | Nonsense Mutation (SNP) | VAF 32/120 reads (27%) | catalogued as COSV99687495; called by muse, mutect2, varscan2
- PGRMC1 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99483585; called by muse, mutect2, varscan2
- PHACTR3 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV100732914; called by muse, mutect2, varscan2
- PHC3 | c.2745G>C p.E915D (on ENST00000494943 / NM_001308116.2; = p.E927D on NM_024947.4) | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101520180; called by muse, mutect2, varscan2
- PHF3 | c.2330C>A p.T777N | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as COSV100013683; called by muse, mutect2, varscan2
- PHLDA3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 12/18 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as COSV100943637; called by mutect2, varscan2
- PLS3 | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1556639026, COSV99171807; called by muse, mutect2, varscan2
- PLSCR2 | c.643G>C p.V215L (on ENST00000497985 / NM_001199978.1; = p.V142L on NM_020359.2) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV100367834, COSV60865150; called by muse, mutect2, varscan2
- PLXNB2 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100834191; called by muse, mutect2, varscan2
- PMFBP1 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as COSV99401265; called by muse, mutect2, varscan2
- POM121L12 | c.323T>A p.L108Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as COSV101374954; called by muse, mutect2, varscan2
- POU3F3 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100796871; called by muse, mutect2
- POU6F2 | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101302787; called by muse, mutect2, varscan2
- PPFIA1 | c.2792G>T p.R931M | Missense Mutation (SNP) | VAF 22/492 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99557814; called by muse, mutect2
- PPFIA2 | c.1799G>T p.W600L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100334513, COSV61028089; called by muse, mutect2, varscan2
- PROM2 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs761599343, COSV58301036; called by muse, mutect2
- PROS1 | c.547del p.H183Tfs*25 | Frame Shift Del (DEL) | VAF 48/103 reads (47%) | catalogued as rs1559935233; called by mutect2, pindel, varscan2
- PRRC2C | c.2492C>G p.P831R (on ENST00000367742; = p.P829R on NM_015172.4) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as COSV100145604; called by muse, mutect2, varscan2
- PRSS58 | c.682T>G p.F228V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV101616081, COSV101616152; called by muse, mutect2, varscan2
- PYHIN1 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100932383; called by muse, mutect2, varscan2
- QDPR | c.439A>G p.M147V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs373431639; called by muse, mutect2, varscan2
- RALGAPB | c.3712G>A p.E1238K | Missense Mutation (SNP) | VAF 167/299 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0.117); catalogued as COSV99485529; called by muse, mutect2, varscan2
- RBM15 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV100873477, COSV63923215; called by muse, mutect2, varscan2
- RDH13 | c.459G>C p.L153F (on ENST00000415061 / NM_001145971.2; = p.L82F on NM_138412.4) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99401579; called by muse, mutect2, varscan2
- RHAG | c.662T>A p.F221Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.124); catalogued as COSV100006739; called by muse, mutect2, varscan2
- RHBDD1 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 64/170 reads (38%) | catalogued as COSV100392035; called by muse, mutect2, varscan2
- RIMS2 | c.4131G>C p.M1377I (on ENST00000666250 / NM_001348490.2; = p.M948I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV51726230, COSV99179108; called by muse, mutect2, varscan2
- RIOX1 | c.197C>G p.S66W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV100408071; called by muse, mutect2
- RIPK3 | c.1546A>T p.S516C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as COSV99353352; called by muse, mutect2, varscan2
- RNF150 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.608); catalogued as rs757292511, COSV100153720, COSV100153881; called by muse, mutect2, varscan2
- RNF185 | c.10A>T p.K4* | Nonsense Mutation (SNP) | VAF 40/147 reads (27%) | catalogued as COSV99839852; called by muse, mutect2, varscan2
- ROBO1 | c.1316C>G p.T439R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101459069; called by muse, mutect2, varscan2
- RUNX1T1 | c.1751C>A p.P584Q (on ENST00000265814 / NM_001198628.1; = p.P557Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV99753565; called by muse, mutect2, varscan2
- RYR1 | c.14206G>A p.E4736K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV62102932; called by muse, mutect2, varscan2
- SAGE1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100187635; called by muse, mutect2, varscan2
- SCN4A | c.3156C>G p.D1052E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101438581; called by muse, mutect2
- SCN5A | c.2618C>T p.S873L | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs794728866, COSV100349625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDC2 | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as rs777002637, COSV100143652, COSV100143813; called by muse, mutect2, varscan2
- SEMA4F | c.1312G>T p.V438L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV100336070; called by muse, mutect2, varscan2
- SERGEF | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99787558; called by muse, mutect2, varscan2
- SERINC1 | c.1272G>C p.W424C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422552786, COSV100305292; called by muse, mutect2
- SETX | c.3863G>T p.G1288V | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99810398; called by muse, mutect2, varscan2
- SH2B3 | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100374414; called by muse, mutect2, varscan2
- SHOC2 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99510365; called by muse, mutect2, varscan2
- SLC12A2 | c.3114G>C p.L1038F | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99321374; called by muse, mutect2, varscan2
- SLC17A4 | c.1064T>C p.L355P | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1323429571, COSV100930642; called by muse, mutect2, varscan2
- SLC20A1 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); catalogued as COSV99734164; called by muse, mutect2, varscan2
- SLC25A37 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99264075; called by muse, mutect2, varscan2
- SLC26A7 | c.477+1G>T p.X159_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99403934; called by muse, mutect2, varscan2
- SLC38A7 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 26/81 reads (32%) | catalogued as COSV99543638, COSV99543863; called by muse, mutect2, varscan2
- SLC41A2 | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99316720; called by muse, mutect2, varscan2
- SLCO1B3 | c.1160C>A p.A387E | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99681938; called by muse, mutect2, varscan2
- SORCS1 | c.2699T>G p.V900G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV99548457; called by muse, mutect2, varscan2
- SP6 | c.191C>A p.S64* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV100647066; called by muse, mutect2, varscan2
- SRGAP1 | c.2080T>G p.F694V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100754944; called by muse, mutect2, varscan2
- SS18 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99294325; called by muse, mutect2, varscan2
- SUN1 | c.1633A>C p.R545= (on ENST00000405266 / NM_001367651.1; = p.R425= on NM_025154.6 and 13 other RefSeq transcripts) | Splice Region (SNP) | VAF 76/211 reads (36%) | catalogued as COSV101273059; called by muse, mutect2, varscan2
- SYCP1 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as COSV101051049; called by muse, mutect2, varscan2
- SYNE1 | c.11115G>C p.Q3705H (on ENST00000367255 / NM_182961.4; = p.Q3690H on NM_033071.3) | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.547); catalogued as COSV54899977, COSV99572956; called by muse, mutect2, varscan2
- SYT3 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV100144218; called by muse, mutect2, varscan2
- TBX20 | c.143A>T p.K48M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV101282375, COSV101282400; called by muse, mutect2, varscan2
- THSD7A | c.1976A>C p.Q659P | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101448814; called by muse, mutect2, varscan2
- THUMPD3 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 107/190 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs760149655, COSV61506435; called by muse, mutect2, varscan2
- TLK2 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100409422; called by muse, mutect2, varscan2
- TLL1 | c.1539C>A p.D513E | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV99288288; called by muse, mutect2, varscan2
- TLR4 | c.1610C>A p.T537K (on ENST00000355622 / NM_138554.5; = p.T497K on NM_003266.4) | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.081); catalogued as COSV100842820; called by muse, mutect2, varscan2
- TM9SF4 | c.847A>T p.I283F | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99454907; called by muse, mutect2, varscan2
- TMPRSS6 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV100696019; called by muse, mutect2, varscan2
- TMPRSS7 | c.2080G>T p.D694Y (on ENST00000452346; = p.D568Y on NM_001042575.2) | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101340144; called by muse, mutect2, varscan2
- TRIM28 | c.2422G>T p.V808L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99449295; called by muse, mutect2, varscan2
- TRIM48 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.2); PolyPhen benign (0.335); catalogued as COSV101338324, COSV101338343; called by muse, mutect2, varscan2
- TRIM51 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 57/99 reads (58%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs373281032, COSV55263856; called by muse, mutect2, varscan2
- TRPC3 | c.2029G>T p.G677W (on ENST00000379645 / NM_001366479.2; = p.G604W on NM_003305.2) | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99313127; called by muse, mutect2, varscan2
- TRPS1 | c.2215G>C p.E739Q (on ENST00000220888 / NM_001330599.2; = p.E752Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99632748; called by muse, mutect2, varscan2
- TTLL7 | c.1799G>C p.R600P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.132); catalogued as COSV53081425, COSV99552775; called by muse, mutect2, varscan2
- TTN | c.84269C>T p.P28090L (on ENST00000591111; = p.P20666L on NM_003319.4) | Missense Mutation (SNP) | VAF 38/98 reads (39%) | PolyPhen probably damaging (0.999); catalogued as COSV100622130; called by muse, mutect2, varscan2
- TTN | c.67750C>A p.P22584T (on ENST00000591111; = p.P15160T on NM_003319.4) | Missense Mutation (SNP) | VAF 62/164 reads (38%) | PolyPhen probably damaging (0.999); catalogued as COSV100622133; called by muse, mutect2, varscan2
- TTN | c.62209C>G p.P20737A (on ENST00000591111; = p.P13313A on NM_003319.4) | Missense Mutation (SNP) | VAF 42/131 reads (32%) | PolyPhen probably damaging (0.997); catalogued as rs1559494860, COSV100599793, COSV100622134; called by muse, mutect2, varscan2
- TTN | c.53528T>A p.V17843E (on ENST00000591111; = p.V10419E on NM_003319.4) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | PolyPhen benign (0.018); catalogued as COSV100622135; called by muse, mutect2, varscan2
- TTN | c.47846G>C p.W15949S (on ENST00000591111; = p.W8525S on NM_003319.4) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | PolyPhen probably damaging (0.998); catalogued as COSV100622139; called by muse, mutect2, varscan2
- TTN | c.29156C>G p.T9719R (on ENST00000591111; = p.T8792R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/176 reads (37%) | PolyPhen possibly damaging (0.812); catalogued as COSV100622142; called by muse, mutect2, varscan2
- TTN | c.24878A>T p.H8293L (on ENST00000591111; = p.H7366L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/62 reads (50%) | PolyPhen benign (0); catalogued as COSV100622145; called by muse, mutect2, varscan2
- TTN | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 31/109 reads (28%) | PolyPhen probably damaging (0.996); catalogued as rs766434493, COSV100589320, COSV59935368; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- U2SURP | c.1768A>G p.K590E | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV101204537; called by muse, mutect2, varscan2
- UBE2Q2 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV99143381; called by muse, mutect2, varscan2
- ULK1 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417116; called by muse, mutect2, varscan2
- UROC1 | c.1564A>G p.I522V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs1028662513, COSV99331998; called by muse, mutect2
- USH2A | c.9646C>A p.L3216M | Missense Mutation (SNP) | VAF 70/89 reads (79%) | SIFT tolerated (0.15); PolyPhen benign (0.275); catalogued as rs368240096, COSV100239012; called by muse, mutect2, varscan2
- USP34 | c.6996G>C p.L2332F | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101277126; called by muse, mutect2, varscan2
- USP38 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100189370; called by muse, mutect2, varscan2
- WDSUB1 | c.1422C>A p.H474Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99714651; called by muse, mutect2, varscan2
- WSCD2 | c.985C>G p.R329G | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99774953, COSV99775470; called by muse, mutect2, varscan2
- ZAN | c.2092A>C p.I698L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.12); catalogued as COSV100769987; called by muse, mutect2, varscan2
- ZDHHC2 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765207594, COSV100025027, COSV50497353; called by muse, mutect2, varscan2
- ZER1 | c.2297G>C p.R766T | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs376528001, COSV99402271; called by muse, varscan2
- ZKSCAN2 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100048419, COSV60156433; called by muse, mutect2, varscan2
- ZNF14 | c.836A>T p.Y279F | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100694104; called by muse, mutect2
- ZNF214 | c.375C>A p.S125R | Missense Mutation (SNP) | VAF 24/447 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV99547554; called by muse, mutect2
- ZNF248 | c.1559A>T p.Y520F | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.135); catalogued as COSV100627672, COSV61997353; called by muse, mutect2, varscan2
- ZNF256 | c.965C>G p.P322R | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56599692, COSV99990950; called by muse, mutect2, varscan2
- ZNF257 | c.725C>G p.S242* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV101448136, COSV71306974; called by muse, mutect2, varscan2
- ZNF263 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99527063; called by muse, mutect2, varscan2
- ZNF514 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 39/116 reads (34%) | catalogued as COSV99727871; called by muse, mutect2, varscan2
- ZNF536 | c.2168C>T p.S723L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100835538, COSV62817472; called by muse, varscan2
- ZNF799 | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101345283; called by muse, mutect2, varscan2
- ZNHIT6 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100995669; called by muse, mutect2, varscan2
- AGAP3 | c.818del p.S273Wfs*103 (on ENST00000622464; = p.S309Wfs*103 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 46/126 reads (37%) | called by mutect2, pindel*, varscan2
- ASAP1 | c.1026del p.W342Cfs*13 | Frame Shift Del (DEL) | VAF 32/105 reads (30%) | called by mutect2, pindel, varscan2
- ASIC1 | c.101_103del p.F34del | In Frame Del (DEL) | VAF 28/86 reads (33%) | called by pindel, varscan2
- ATP1A4 | c.2622del p.Y875Tfs*3 | Frame Shift Del (DEL) | VAF 29/131 reads (22%) | called by mutect2, pindel, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by pindel, varscan2
- FZD5 | c.670C>G p.Q224E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, mutect2
- IGHV1-45 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIR3DL3 | c.764T>A p.L255Q | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRK2 | c.7403dup p.N2468Kfs*14 | Frame Shift Ins (INS) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- ORM2 | c.315del p.V106Sfs*23 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | called by mutect2, pindel, varscan2
- RALGAPA1 | c.3883dup p.C1295Lfs*2 | Frame Shift Ins (INS) | VAF 65/164 reads (40%) | called by mutect2, pindel, varscan2
- RING1 | c.975_981del p.D325Efs*49 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel
- SOBP | c.375del p.I126Lfs*5 | Frame Shift Del (DEL) | VAF 69/159 reads (43%) | called by mutect2, pindel, varscan2
- TRAPPC13 | c.146A>T p.D49V | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.807); called by muse, mutect2
- TTN | c.81118del p.A27040Pfs*3 (on ENST00000591111; = p.A19616Pfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | called by mutect2, pindel, varscan2
- YTHDC2 | c.188-1G>C p.X63_splice | Splice Site (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2
- A1BG | c.1434C>T p.H478= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99568520; called by muse, mutect2, varscan2
- AFF3 | c.942A>T p.P314= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100419676; called by muse, mutect2, varscan2
- AGMO | c.291T>C p.Y97= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as COSV100694492; called by muse, mutect2, varscan2
- AL592490.1 | c.1932C>T p.F644= | Silent (SNP) | VAF 45/86 reads (52%) | catalogued as rs149653186; called by muse, mutect2, varscan2
- ALDH3A2 | c.1179G>A p.T393= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs372428552; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANO3 | c.129C>T p.S43= | Silent (SNP) | VAF 62/227 reads (27%) | catalogued as COSV99884297; called by muse, mutect2, varscan2
- ATP8A2 | c.2172G>A p.Q724= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as COSV99683206; called by muse, mutect2, varscan2
- BTBD7 | c.525A>G p.P175= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV100108097; called by muse, mutect2, varscan2
- CCDC39 | c.2475C>T p.D825= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV56491504, COSV99870049; called by muse, mutect2
- CCL3 | c.210G>T p.R70= | Silent (SNP) | VAF 34/116 reads (29%) | called by muse, mutect2, varscan2
- CDK12 | c.4122G>A p.R1374= (on ENST00000447079 / NM_016507.4; = p.R1365= on NM_015083.3) | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- CHRNA4 | c.1032A>G p.V344= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as rs756373981, COSV100937457; called by muse, mutect2, varscan2
- CLN5 | c.33C>G p.A11= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs530381028, COSV101080387; called by muse, mutect2, varscan2
- CLPTM1 | c.1446C>T p.I482= | Silent (SNP) | VAF 55/174 reads (32%) | catalogued as COSV100493881; called by muse, mutect2, varscan2
- CNOT4 | c.1296G>T p.S432= (on ENST00000315544 / NM_001190848.1; = p.S429= on NM_013316.4) | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as COSV100211943; called by muse, mutect2, varscan2
- CNTN3 | c.2226T>A p.P742= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV99725456; called by muse, mutect2, varscan2
- CSPG4 | c.5643C>T p.L1881= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs761588421, COSV100413944; called by muse, mutect2, varscan2
- CYP17A1 | c.1089C>T p.L363= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV100882125; called by muse, mutect2, varscan2
- CYP2C9 | c.873A>G p.A291= | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as COSV99582968; called by muse, mutect2, varscan2
- DDX58 | c.1842C>T p.L614= | Silent (SNP) | VAF 100/292 reads (34%) | catalogued as COSV101153091; called by muse, mutect2, varscan2
- DHRS2 | c.132C>A p.S44= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV99159719; called by muse, mutect2, varscan2
- DOCK3 | c.1695G>A p.L565= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV99813788; called by muse, mutect2, varscan2
- ECT2 | c.535C>T p.L179= (on ENST00000392692 / NM_001349098.2; = p.L148= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as COSV99221607; called by muse, mutect2, varscan2
- ERBB4 | c.2358G>T p.V786= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV100726585; called by muse, mutect2, varscan2
- FBXO10 | c.2268G>A p.G756= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV99446989; called by muse, mutect2, varscan2
- FILIP1 | c.3591G>A p.L1197= | Silent (SNP) | VAF 73/175 reads (42%) | catalogued as COSV99383771; called by muse, mutect2, varscan2
- FOXD4 | c.210C>T p.I70= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as COSV58700148; called by muse, mutect2, varscan2
- FOXO4 | c.882G>T p.G294= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV100446995; called by muse, mutect2, varscan2
- GABRR3 | c.402A>G p.R134= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs1323086174, COSV101512326; called by muse, mutect2, varscan2
- GNE | c.2205C>T p.P735= (on ENST00000396594 / NM_001128227.3; = p.P704= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs779967033, CD156985, COSV64952525; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPC5 | c.156G>A p.P52= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV65608936; called by muse, mutect2, varscan2
- GRIN3A | c.1095G>A p.L365= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs762083662, COSV100701672; called by muse, mutect2, varscan2
- HAVCR2 | c.717C>T p.L239= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV100324880; called by muse, mutect2, varscan2
- IGHV3-13 | c.207T>C p.A69= | Silent (SNP) | VAF 56/179 reads (31%) | catalogued as rs782003789; called by muse, mutect2, varscan2
- KNTC1 | c.2295T>C p.N765= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs768380870, COSV61080258; called by muse, mutect2, varscan2
- L3HYPDH | c.342C>T p.F114= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs200875616, COSV99711694; called by muse, varscan2
- LRATD1 | c.345G>A p.A115= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs763582614, COSV99707213; called by muse, mutect2, varscan2
- LRRC4C | c.1173A>G p.G391= | Silent (SNP) | VAF 59/238 reads (25%) | catalogued as COSV99539037; called by muse, mutect2, varscan2
- MAGEA3 | c.552C>T p.L184= | Silent (SNP) | VAF 70/123 reads (57%) | catalogued as COSV100939072; called by muse, mutect2, varscan2
- MED12 | c.3405C>T p.L1135= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100379120; called by muse, mutect2, varscan2
- MMP16 | c.1099C>A p.R367= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV54175541, COSV99689503; called by muse, mutect2, varscan2
- MOCS3 | c.279C>T p.L93= | Silent (SNP) | VAF 50/208 reads (24%) | catalogued as rs750783055, COSV99724427; called by muse, mutect2, varscan2
- NCKAP1 | c.879C>T p.L293= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV100720451; called by muse, mutect2, varscan2
- NDC1 | c.303C>T p.S101= | Silent (SNP) | VAF 41/72 reads (57%) | catalogued as rs749991839, COSV99323817; called by muse, mutect2, varscan2
- NKX2-3 | c.249G>A p.G83= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1388715899, COSV100755116; called by muse, mutect2, varscan2
- NUP58 | c.1287T>G p.V429= | Silent (SNP) | VAF 32/57 reads (56%) | catalogued as COSV101098851; called by muse, mutect2, varscan2
- OR1K1 | c.351G>C p.A117= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV99474333; called by muse, mutect2, varscan2
- OR2AK2 | c.894G>C p.T298= | Silent (SNP) | VAF 52/81 reads (64%) | catalogued as COSV100824168, COSV63553745, COSV63556785; called by muse, mutect2, varscan2
- OR51D1 | c.447G>A p.L149= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV100712414; called by muse, mutect2, varscan2
- PCDHA7 | c.1698G>T p.L566= | Silent (SNP) | VAF 92/150 reads (61%) | catalogued as COSV100971667; called by muse, mutect2, varscan2
- PDILT | c.1089C>A p.G363= | Silent (SNP) | VAF 62/108 reads (57%) | catalogued as COSV100199659; called by muse, mutect2, varscan2
- PLPP7 | c.55C>A p.R19= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV64835896; called by muse, mutect2, varscan2
- PRDM12 | c.738C>T p.V246= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1475621117, COSV99446299; called by muse, mutect2
- PTPN11 | c.1776C>T p.F592= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100692805; called by muse, mutect2, varscan2
- PXDN | c.2865G>A p.P955= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs544934849, COSV99412662; called by muse, mutect2, varscan2
- RAPGEF4 | c.1269G>A p.K423= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as COSV99911174; called by muse, mutect2, varscan2
- RHBDD1 | c.381C>T p.A127= | Silent (SNP) | VAF 53/166 reads (32%) | catalogued as rs750293564, COSV100392056; called by muse, mutect2, varscan2
- RNGTT | c.303G>A p.E101= | Silent (SNP) | VAF 31/143 reads (22%) | catalogued as COSV99667075; called by muse, mutect2, varscan2
- RPIA | c.57C>T p.P19= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs780586313, COSV99376360; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.3213C>A p.I1071= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV101213327, COSV66777068; called by muse, mutect2, varscan2
- SLC12A5 | c.2163G>A p.L721= (on ENST00000454036 / NM_001134771.2; = p.L698= on NM_020708.5) | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99716471; called by muse, mutect2, varscan2
- SLC25A42 | c.738G>A p.P246= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100588164; called by muse, mutect2, varscan2
- SLC33A1 | c.1038C>T p.A346= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as rs759587119, COSV100848323; called by muse, mutect2, varscan2
- SLC4A2 | c.1128C>G p.L376= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100055629; called by muse, mutect2
- TBC1D9B | c.3564C>T p.I1188= (on ENST00000356834 / NM_198868.3; = p.I1171= on NM_015043.4) | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs568670516, COSV99481681; called by muse, mutect2, varscan2
- TMEM177 | c.807G>A p.E269= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs143570418; called by muse, mutect2, varscan2
- TNPO3 | c.1695A>C p.T565= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99603241; called by muse, mutect2, varscan2
- TNS1 | c.3300C>T p.D1100= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV99411386; called by muse, mutect2, varscan2
- TP53AIP1 | c.21G>T p.A7= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV101513104, COSV71688717; called by muse, mutect2, varscan2
- TRABD2A | c.510C>G p.L170= | Silent (SNP) | VAF 46/168 reads (27%) | catalogued as rs780641384, COSV100120084; called by muse, mutect2, varscan2
- TRIM49 | c.489C>A p.T163= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100316170; called by muse, mutect2, varscan2
- TUBGCP6 | c.1953C>G p.A651= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV99955995; called by muse, mutect2, varscan2
- UBQLN3 | c.189A>T p.L63= | Silent (SNP) | VAF 43/143 reads (30%) | catalogued as COSV100293850; called by muse, mutect2, varscan2
- WBP1L | c.984C>T p.N328= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs374884605; called by muse, mutect2, varscan2
- XCR1 | c.636G>C p.L212= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100499425; called by muse, mutect2, varscan2
- XK | c.726C>G p.L242= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV101064751; called by muse, mutect2, varscan2
- AMACR | c.739+1139C>G | Intron (SNP) | VAF 16/26 reads (62%) | catalogued as COSV100163181; called by muse, mutect2, varscan2
- C17orf67 | c.-51G>T | 5'UTR (SNP) | VAF 15/51 reads (29%) | catalogued as COSV101190999; called by muse, mutect2, varscan2
- CCNQP1 | n.523G>A | RNA (SNP) | VAF 61/113 reads (54%) | catalogued as rs182006504; called by muse, mutect2, varscan2
- GNAO1 | c.723+3972A>T | Intron (SNP) | VAF 111/356 reads (31%) | catalogued as COSV99341505; called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.91C>T | RNA (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.291+11197C>A | Intron (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100541531, COSV100542279; called by muse, mutect2, varscan2
- MGAM | c.4618+10752G>C | Intron (SNP) | VAF 32/103 reads (31%) | catalogued as COSV101527611; called by muse, mutect2, varscan2
- MIR29A | n.41C>G | RNA (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- RIMS2 | c.4064-21177G>C | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99179100; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12729T>G | Intron (SNP) | VAF 17/75 reads (23%) | catalogued as COSV101044436; called by muse, mutect2, varscan2
- TMX3 | c.*1G>C | 3'UTR (SNP) | VAF 44/77 reads (57%) | catalogued as COSV100218468; called by muse, mutect2, varscan2
- TTN | c.10360+2720C>T | Intron (SNP) | VAF 48/136 reads (35%) | catalogued as COSV100622147; called by muse, mutect2, varscan2
- TUBB7P | n.912C>A | RNA (SNP) | VAF 50/93 reads (54%) | called by muse, mutect2, varscan2
